Gene-level copy-number profile of tumor specimen TCGA-QR-A705-01A from TCGA case TCGA-QR-A705, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Extra-adrenal paraganglioma, NOS; Tissue or organ of origin: Heart; Age at diagnosis: 63.2 years (23,086 days).
Specimen TCGA-QR-A705-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PCPG.a8a6cbb7-17c7-4b08-bcef-a3cba25d6a30.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QR-A705-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: AscatNGS.
https://portal.gdc.cancer.gov/files/7beb69ce-971b-4e11-a204-23e278a28639

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 43; copy number 1: 7,825; copy number 2: 51,834; copy number 3: 118.

Homozygous deletions (total copy number 0; autosomes only): 42 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:158,418,210–158,426,237, 1 gene: OR10K2.
- chr2:35,219,377–35,219,604, 1 gene: SMIM7P1.
- chr2:185,738,804–185,833,290, 1 gene (within-gene range 0–2): FSIP2.
- chr5:125,966,777–125,968,085, 1 gene: RPSAP37.
- chr5:155,491,336–155,493,598, 1 gene: AC008725.1.
- chr6:85,257,328–85,257,694, 1 gene: AL122016.1.
- chr7:62,275,361–62,275,678, 1 gene: AC128676.1.
- chr8:46,810,696–46,907,309, 9 genes (within-gene range 0–2): AC021451.2, AC021451.3, LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3.
- chr8:139,108,430–139,127,953, 2 genes: AC100807.1, AC100807.2.
- chr11:21,260,061–21,383,909, 3 genes: AC090857.2, AC099730.1, RNA5SP337.
- chr11:81,552,226–81,556,425, 2 genes: MTND4LP18, MTND6P25.
- chr11:92,161,106–92,336,496, 2 genes: RPL7AP57, NDUFB11P1.
- chr11:92,366,496–92,498,935, 3 genes: PGAM1P9, AP000722.1, RPS3AP42.
- chr11:124,302,831–124,384,462, 8 genes: OR8D1, OR8D2, OR8B7P, OR8B6P, OR8B5P, OR8B1P, OR8C1P, OR8B2.
- chr12:46,764,761–46,832,408, 1 gene (within-gene range 0–2): SLC38A4.
- chr16:52,198,012–52,227,956, 1 gene (within-gene range 0–1): AC007333.2.
- chr19:27,638,483–27,794,005, 4 genes (within-gene range 0–2): ERVK-28, AC112702.1, LINC00662, AC006504.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 7,778. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
